TCGA case TCGA-AL-3467 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Fox Chase. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4d02010e-9e69-40d3-9bf0-3d4510aa0614

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 54 years; Vital status: Alive.

Diagnoses (1)
1. Papillary adenocarcinoma, NOS: ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 54.2 years (19,783 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: M0; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 2,135 days (5.8 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,778 days (4.9 years); Disease response: Tumor Free.
- Days to follow up: 2,135 days (5.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Calcium: Normal.
- Hemoglobin: Normal.
- Leukocytes: Normal.
- Platelets: Normal.
- Lactate Dehydrogenase: Normal.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 59 kg; Height: 152 cm; BMI: 25.5.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AL-3467-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.9; Intermediate dimension: 0.9; Shortest dimension: 0.3.
  Slide TCGA-AL-3467-01A-01-BS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5.
  Slide TCGA-AL-3467-01A-01-TS1: Section location: Top; Percent tumor cells: 92; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 5.
  Slide TCGA-AL-3467-01A-02-BS2: Section location: Bottom; Percent tumor cells: 98; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 2.
- Sample TCGA-AL-3467-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AL-3467-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Lymph nodes examined: No; Tobacco smoking history indicator: 1.
- Follow-up form 1: Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No.
- Follow-up form 2: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,135 days; disease-specific survival: no event (censored), 2,135 days; disease-free interval: no event (censored), 2,135 days; progression-free interval: no event (censored), 2,135 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AL-3467-01A-02D-1348-01): tumor purity 0.67, ploidy 2, whole-genome doublings 0.
